Somatic mutation profile of tumor specimen TARGET-30-PASYLD-01A (aliquot TARGET-30-PASYLD-01A-01D) from TARGET case TARGET-30-PASYLD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 5.5 years (2,015 days).
Specimen TARGET-30-PASYLD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4879f2e-7e6c-46b9-bce1-9e6bc2b9af6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASYLD-10A (Blood Derived Normal), aliquot TARGET-30-PASYLD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2773999-5bb9-4023-b891-936304a61515

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN1 | c.2380C>G p.R794G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV51997563; called by muse, mutect2, varscan2
- AHNAK2 | c.7467G>C p.K2489N | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100315932, COSV60930564; called by muse, mutect2, varscan2
- BCL11A | c.1835C>T p.P612L (on ENST00000335712 / NM_001365609.1; = p.P646L on NM_018014.4) | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs770749600, COSV59636957; called by muse, mutect2, varscan2
- BLM | c.2675T>C p.I892T | Missense Mutation (SNP) | VAF 67/333 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61927375; called by muse, mutect2, varscan2
- E2F7 | c.221A>G p.D74G | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV59743498; called by muse, mutect2, varscan2
- HK2 | c.65T>A p.V22D | Missense Mutation (SNP) | VAF 59/357 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51879620; called by muse, mutect2, varscan2
- HPSE | c.1316A>T p.N439I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100264167, COSV60988793; called by muse, mutect2, varscan2
- INPP5B | c.1197G>C p.E399D (on ENST00000373023; = p.E319D on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV65963055; called by muse, mutect2, varscan2
- MYOM1 | c.2143T>G p.S715A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV55301193; called by muse, mutect2, varscan2
- NPHP4 | c.2927C>G p.T976S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV65393435, COSV65397994; called by muse, mutect2, varscan2
- NR4A3 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.962); catalogued as COSV58248307; called by muse, mutect2
- POF1B | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as COSV53140600; called by muse, mutect2, varscan2
- SLFN11 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARAP1 | c.3684G>A p.R1228= (on ENST00000393609 / NM_001040118.2; = p.R983= on NM_015242.4) | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs1277768491, COSV61995033; called by muse, mutect2, varscan2
- HCFC1 | c.2730C>T p.I910= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV60077749; called by muse, mutect2, varscan2
- NID1 | c.255T>C p.S85= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV51628961; called by muse, mutect2, varscan2
- PDS5A | c.3213A>T p.T1071= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV57831229; called by muse, mutect2, varscan2
- SLC4A10 | c.1287T>G p.P429= (on ENST00000446997 / NM_001354461.2; = p.P399= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV55799583, COSV55803252; called by muse, mutect2, varscan2
